Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5876, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5876-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

1: Right kidney; partial nephrectomy

DIAGNOSIS:

1. Right kidney; partial nephrectomy:

- PAPILLARY RENAL CELL CARCINOMA, TYPE B, (HIGH GRADE).
- TUMOR MEASURES 1.3 CM.
- TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- SURGICAL MARGIN IS FREE OF TUMOR (TUMOR IS 0.2 CM FROM THE RESECTION MARGIN).
- INCIDENTAL PAPILLARY "ADENOMA" (1.0 MM).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

1) The specimen is received fresh for frozen section, labeled "Right Kidney Tumor". It consists of a piece of renal cortex measuring 4 x 3.5 x 1 cm. Sectioning of the tissue reveals a well-circumscribed, cystic tumor measuring 1.3 x 0.5 x 2 cm, filled with gray-tan, soft, cheesy material. The tissue surgical margin is inked black. The tumor is 0.2 cm away from the surgical margin. A portion of tissue is submitted for TPS. Photographs are taken. Representative sections are submitted for histologic examination.

Summary of Sections:

FSC - frozen section control

T - tumor

Summary of Sections:

Part 1: Right kidney; partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
4	ss	4
3	t	3

[page 2 of 2]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM; STITCHED MARGIN IS FREE OF TUMOR.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file f7c718eb-af70-4123-80c8-93e1a7a31b16 (TCGA-BQ-5876.6DD5E138-F74B-4777-9001-533EECE6076A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).